Gene-level copy-number profile of specimen HCM-SANG-0549-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0549-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0549-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 342b4ab3-27db-4e29-9258-a4ff832a5073.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0549-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/16e08a3a-38e0-493a-932e-4c95f28dabd4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 529; copy number 1: 3,344; copy number 2: 43,115; copy number 3: 8,536; copy number 4: 2,953; copy number 5: 256; copy number 6: 66; copy number 7: 2; copy number 8: 98; copy number 12: 2.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–3): AL359922.1.
- chr9:21,892,188–21,995,301, 4 genes (within-gene range 0–3): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes (within-gene range 0–2): AL449423.1, CDKN2B, UBA52P6.
- chr9:61,581,813–61,662,690, 4 genes: AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr18:50,967,991–51,218,333, 5 genes: ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C.
- chr22:18,833,694–18,834,438, 1 gene (within-gene range 0–3): E2F6P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 424 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:31,053,565–45,895,970, 242 genes, copy number 5 (broad region; genes not listed).
- chr8:8,701,937–12,043,670, 97 genes, copy number 8 (broad region; genes not listed).
- chr9:64,369,394–64,413,142, 2 genes, copy number 7: ANKRD20A4P, RNU6-1193P.
- chr9:64,810,865–64,811,429, 1 gene, copy number 6: BNIP3P4.
- chr9:65,219,987–65,285,209, 3 genes, copy number 8–12: AL512605.1, AL512605.2, FOXD4L5.
- chr9:66,014,525–66,043,342, 5 genes, copy number 5: AL136317.2, AL136317.1, GXYLT1P4, AL136317.3, AL669942.2.
- chr12:21,131,194–24,562,544, 39 genes, copy number 6 (within-gene range 4–6): SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1, SOX5, AC087260.1.
- chr12:30,628,988–30,879,268, 6 genes, copy number 5: IPO8, CAPRIN2, AC010198.1, LINC00941, AC010198.2, PPIAP44.
- chr12:32,072,734–32,072,880, 1 gene, copy number 5: AC048344.2.
- chr21:7,744,962–8,454,792, 26 genes, copy number 6: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.
- chr22:18,873,543–18,894,407, 2 genes, copy number 5: FAM230F, AC008103.1.

Autosomal genes at a single copy (total copy number 1): 3,344. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
